Gene-level copy-number profile of tumor specimen TCGA-ED-A66X-01A from TCGA case TCGA-ED-A66X, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 35.4 years (12,947 days).
Specimen TCGA-ED-A66X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.8675757c-340c-454b-87ef-6cdb3b94f90e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ED-A66X-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/71ca2bb2-554b-4f1a-97b3-3f52414c1462

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,248; copy number 2: 40,222; copy number 3: 3,344; copy number 4: 1,614; copy number 5: 1,360; copy number 6: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ED-A66X-01A-11D-A30U-01): tumor purity 0.45, ploidy 5.41, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,390 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:66,432,486–78,153,913, 173 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:80,204,606–145,066,685, 1,034 genes, copy number 5–6 (broad region; genes not listed).
- chr16:24,098,239–27,780,369, 61 genes, copy number 5 (broad region; genes not listed).
- chr18:47,390–5,989,369, 121 genes, copy number 5 (broad region; genes not listed).
- chr18:5,956,101–5,960,785, 1 gene, copy number 5: AP001021.2.

Autosomal genes at a single copy (total copy number 1): 10,889. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
